MMRF case MMRF_1739 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/116f4352-4b34-4139-ba0d-84b99ef1beb9

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 45.4 years (16,576 days); ISS stage: III; Days to last known disease status: 1,086 days (3.0 years); Days to last follow up: 1,086 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 253 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 155 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days; Days to treatment end: 256 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 289 days; Days to treatment end: 289 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 525 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 734 days (2.0 years); Days to treatment end: 1,100 days (3.0 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,101 days (3.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 6.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 810 mg/dL; Immunoglobulin G 88.1 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 11.6 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 10.7 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 534 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.1 mmol/L; Albumin 16 g/L; Total Protein 13 g/dL; Glucose 6 mmol/L; C-Reactive Protein 3.71 mg/dL.
- Day 85 (ECOG 1): M Protein 3.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 246 mg/dL; Immunoglobulin G 48.9 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 286 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 1.98 mmol/L; Albumin 29 g/L; Total Protein 9.7 g/dL; Glucose 7.1 mmol/L.
- Day 176 (ECOG 1): M Protein 3.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 150 mg/dL; Immunoglobulin G 52.3 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 373 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 11.4 g/dL; Glucose 5.5 mmol/L.
- Day 281 (ECOG 1): M Protein 0.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.28 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.74 g/L; Beta 2 Microglobulin 2.05 µg/mL; Lactate Dehydrogenase 4.1 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 42.2 ×10⁹/L; Absolute Neutrophil 32.9 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 7.2 g/dL; Glucose 9.46 mmol/L.
- Day 349 (ECOG 1): M Protein 0.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 2.03 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 2.16 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 316 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 6.16 mmol/L.
- Day 442 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 2.08 g/L; Immunoglobulin M 0.9 g/L; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 294 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 8.1 g/dL; Glucose 5.89 mmol/L.
- Day 533: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 12.6 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 10.7 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 370 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 7.8 g/dL; Glucose 5.12 mmol/L.
- Day 624: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.24 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 2.32 g/L; Immunoglobulin M 1.53 g/L; Lactate Dehydrogenase 1.55 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 311 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.6 g/dL; Glucose 6.49 mmol/L.
- Day 720: M Protein 0.92 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 25.4 mg/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 2.11 g/L; Immunoglobulin M 1.13 g/L; Beta 2 Microglobulin 2.07 µg/mL; Lactate Dehydrogenase 4.12 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 307 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 4.57 mmol/L.
- Day 820: M Protein 0.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.08 mg/dL; Immunoglobulin G 10.1 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 39.2 g/L; Total Protein 6.8 g/dL; Glucose 4.35 mmol/L.
- Day 911: M Protein 0.45 g/dL; Immunoglobulin G 7.76 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.2 mmol/L; Albumin 33.9 g/L; Total Protein 6.1 g/dL; Glucose 4.95 mmol/L.
- Day 988: M Protein 0.61 g/dL; Immunoglobulin G 8.7 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 10.3 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 315 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 5.28 mmol/L.
- Day 1,086: M Protein 1.47 g/dL; Immunoglobulin G 22.9 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 335 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 7.1 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day 1: Weight: 44 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1739_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1739_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
